Gene-level copy-number profile of tumor specimen TCGA-13-1819-02A from TCGA case TCGA-13-1819, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 59.2 years (21,635 days).
Specimen TCGA-13-1819-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.72ad27c7-97de-48bf-9857-61ab7488e078.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1819-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/52694981-4799-4dbf-8654-af6d99b7af50

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 610; copy number 1: 1,935; copy number 2: 14,850; copy number 3: 9,468; copy number 4: 20,786; copy number 5: 8,507; copy number 6: 2,389; copy number 7: 1,346; copy number 8: 276; copy number 9: 7; copy number 11: 89; copy number 13: 1; copy number 14: 4; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,177,234–112,360,625, 1 gene (within-gene range 0–4): LINC02884.
- chr2:64,450,096–64,461,381, 2 genes: AC008074.1, LGALSL.
- chr4:10,199,823–10,268,231, 5 genes: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2.
- chr4:77,350,370–77,351,235, 1 gene: AC008638.1.
- chr9:34,665,607–34,691,276, 2 genes (within-gene range 0–7): AL162231.2, CCL19.
- chr9:34,709,005–34,710,136, 1 gene: CCL21.
- chr10:20,547,171–20,552,046, 2 genes: AL590032.1, MIR4675.
- chr10:52,389,112–52,389,488, 1 gene: RPL31P44.
- chr11:62,296,281–62,299,075, 1 gene: SCGB1D4.
- chr12:11,196,075–11,251,389, 2 genes (within-gene range 0–1): AC244131.1, AC244131.2.
- chr12:114,077,133–114,113,489, 4 genes: AC010183.1, AC010183.2, HAUS8P1, GLULP5.
- chr12:118,645,315–119,163,051, 11 genes (within-gene range 0–2): LINC02460, RPL17P37, LINC02423, LINC02440, LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4, AC087885.1, RN7SL508P.
- chr15:34,651,135–34,671,095, 2 genes: LINC02252, AC100834.2.
- chr17:33,013,087–34,174,964, 1 gene (within-gene range 0–2): ASIC2.
- chr17:33,529,787–34,156,000, 17 genes (within-gene range 0–2): AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3.
- chr18:45,104,361–45,683,688, 6 genes (within-gene range 0–3): AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2.
- chr20:62,463,497–62,573,384, 8 genes (within-gene range 0–4): GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 95 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,211,487–198,222,513, 79 genes, copy number 11 (broad region; genes not listed).
- chr8:97,853,021–97,865,485, 3 genes, copy number 11: AP002906.1, SUMO2P18, RPS23P1.
- chr9:31,253,901–31,381,490, 2 genes, copy number 13–16: SLC25A6P2, LINC01243.
- chr11:129,761,713–129,814,690, 2 genes, copy number 11: AP003327.2, AP003327.1.
- chr13:63,783,801–63,844,125, 4 genes, copy number 14: RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P.
- chr13:86,909,586–86,937,108, 1 gene, copy number 11: LINC00430.
- chr16:78,495,926–78,553,296, 4 genes, copy number 11 (within-gene range 5–11): AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Autosomal genes at a single copy (total copy number 1): 1,914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
